Somatic mutation profile of tumor specimen TCGA-CN-5356-01A (aliquot TCGA-CN-5356-01A-01D-1434-08) from TCGA case TCGA-CN-5356, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 56.2 years (20,540 days).
Specimen TCGA-CN-5356-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ff8c875-a9b1-4254-937c-21b35aa954cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5356-10A (Blood Derived Normal), aliquot TCGA-CN-5356-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e6f9efc-4e00-4883-8927-ef00ecff34b8

The open-access MAF lists 389 somatic variants for this specimen: 289 protein-altering or splice-affecting, 87 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 87, Nonsense Mutation 27, Frame Shift Del 8, Frame Shift Ins 8, Splice Site 7, RNA 6, Intron 4, Splice Region 2, 3'UTR 2, Translation Start Site 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 34/71 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- A1BG | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 109/216 reads (50%) | catalogued as COSV99568123; called by muse, mutect2, varscan2
- A1CF | c.1427G>C p.R476T (on ENST00000373993 / NM_138932.2; = p.R468T on NM_014576.4) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as COSV99255202; called by muse, mutect2, varscan2
- ABCA12 | c.1150G>A p.V384M (on ENST00000272895 / NM_173076.3; = p.V66M on NM_015657.3) | Missense Mutation (SNP) | VAF 109/339 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99788149; called by muse, mutect2, varscan2
- ABCB5 | c.3542A>G p.E1181G (on ENST00000404938 / NM_001163941.2; = p.E736G on NM_178559.6) | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778620806, COSV99327333; called by muse, mutect2, varscan2
- ACSM1 | c.742T>C p.F248L | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99532477; called by muse, mutect2, varscan2
- ADAM28 | c.1543C>A p.Q515K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99737653; called by muse, mutect2, varscan2
- ADAMTS16 | c.1960G>T p.E654* | Nonsense Mutation (SNP) | VAF 12/152 reads (8%) | catalogued as COSV56990630; called by muse, mutect2
- ADAMTSL1 | c.4581C>G p.C1527W | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101000416, COSV65878061; called by muse, mutect2, varscan2
- ADGRB2 | c.511C>A p.R171S | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.501); catalogued as COSV57078850, COSV99925645; called by muse, mutect2, varscan2
- ADGRE1 | c.1279G>T p.A427S | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV99165021; called by muse, mutect2, varscan2
- ADGRF2 | c.2038A>T p.I680F (on ENST00000296862 / NM_001368115.2; = p.I612F on NM_153839.7) | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99730645; called by muse, mutect2, varscan2
- ADGRL3 | c.3557T>C p.F1186S (on ENST00000506720 / NM_001322402.2; = p.F1118S on NM_015236.6) | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101546837; called by muse, mutect2, varscan2
- AFF2 | c.1583G>A p.W528* | Nonsense Mutation (SNP) | VAF 120/232 reads (52%) | catalogued as COSV99661258; called by muse, mutect2, varscan2
- AGBL5 | c.1756C>T p.L586F | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100548824; called by muse, mutect2, varscan2
- AKAP9 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as COSV100661871; called by muse, mutect2, varscan2
- ALDH1A2 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as COSV99990247; called by muse, mutect2, varscan2
- ALMS1 | c.9661A>G p.N3221D | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100041044; called by muse, mutect2, varscan2
- AMY2B | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 54/363 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100796166, COSV63717326; called by muse, mutect2, varscan2
- ANKRD30A | c.2990G>A p.C997Y (on ENST00000611781; = p.C941Y on NM_052997.2) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV100652875; called by muse, mutect2, varscan2
- ANKS1B | c.3128C>A p.T1043N (on ENST00000547776 / NM_152788.4; = p.T209N on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as rs1295714424, COSV100227123; called by muse, mutect2, varscan2
- ANP32D | c.374T>A p.V125E | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99874224; called by muse, mutect2, varscan2
- ANXA2R | c.22T>A p.C8S | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.06); catalogued as COSV100148609; called by muse, mutect2, varscan2
- ANXA7 | c.1288A>T p.K430* (on ENST00000372919 / NM_001320880.2; = p.K408* on NM_001156.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/107 reads (10%) | catalogued as COSV100873396; called by muse, mutect2
- AP3D1 | c.3165-2A>G p.X1055_splice | Splice Site (SNP) | VAF 82/282 reads (29%) | catalogued as COSV100642381; called by muse, mutect2, varscan2
- ARHGAP31 | c.3055C>T p.P1019S | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs375426216, COSV51797123; called by muse, mutect2, varscan2
- ARHGEF12 | c.3986G>A p.R1329Q | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); catalogued as rs770268450, COSV100755005, COSV63104928; called by muse, mutect2, varscan2
- ATP12A | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 38/118 reads (32%) | catalogued as COSV99516957, COSV99518255; called by muse, varscan2
- ATR | c.5398T>A p.W1800R | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100637651; called by muse, mutect2, varscan2
- BARHL2 | c.5C>A p.T2K | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.95); catalogued as COSV100966015; called by muse, mutect2, varscan2
- BBS9 | c.1388C>G p.P463R | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.095); catalogued as COSV99625757; called by muse, mutect2, varscan2
- BCORL1 | c.4472+1G>A p.X1491_splice | Splice Site (SNP) | VAF 55/106 reads (52%) | catalogued as COSV99498365; called by muse, mutect2, varscan2
- BIRC6 | c.12646G>T p.V4216F | Missense Mutation (SNP) | VAF 106/443 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101427822; called by muse, mutect2, varscan2
- BRD8 | c.2299C>T p.R767* (on ENST00000254900 / NM_139199.2; = p.R840* on NM_006696.4) | Nonsense Mutation (SNP) | VAF 16/125 reads (13%) | catalogued as COSV50160038; called by muse, mutect2, varscan2
- BRD9 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.696); catalogued as COSV100056814; called by muse, mutect2, varscan2
- BTNL3 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 27/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100732168; called by muse, mutect2, varscan2
- C12orf66 | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1166415984, COSV100320534; called by muse, mutect2, varscan2
- CACNA1F | c.2597C>A p.T866N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV100544333; called by muse, mutect2, varscan2
- CADM1 | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100522080; called by muse, mutect2, varscan2
- CAMSAP3 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV99349787; called by muse, mutect2
- CCNA1 | c.1132C>G p.P378A | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV55220648, COSV99714280; called by muse, mutect2, varscan2
- CD8A | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 48/222 reads (22%) | catalogued as COSV99374189; called by muse, mutect2, varscan2
- CDH20 | c.826C>G p.Q276E | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as COSV99404239; called by muse, mutect2, varscan2
- CDH9 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 63/229 reads (28%) | catalogued as COSV50304155, COSV99141430; called by muse, mutect2, varscan2
- CDK11B | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.729); catalogued as COSV100477229; called by muse, mutect2, varscan2
- CDKL5 | c.479T>G p.L160R | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV101184011; called by muse, mutect2, varscan2
- CDON | c.1028G>C p.C343S | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as rs1237984326, COSV99700550; called by muse, mutect2, varscan2
- CEP126 | c.3286A>G p.T1096A | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99680536; called by muse, mutect2, varscan2
- CHD8 | c.5336G>T p.R1779L (on ENST00000646647 / NM_001170629.2; = p.R1500L on NM_020920.4) | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.206); catalogued as COSV100765242; called by muse, mutect2, varscan2
- CLSTN2 | c.536T>C p.L179P | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101515517; called by muse, mutect2, varscan2
- CMYA5 | c.5284A>T p.K1762* | Nonsense Mutation (SNP) | VAF 15/113 reads (13%) | catalogued as COSV101483806; called by muse, mutect2, varscan2
- CNDP1 | c.1238T>C p.L413P | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.964); catalogued as COSV100722167; called by muse, mutect2, varscan2
- CNKSR3 | c.1494C>G p.D498E | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101401283; called by muse, mutect2, varscan2
- CNTN5 | c.2857T>C p.Y953H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV99672567; called by muse, mutect2, varscan2
- COL20A1 | c.1663C>A p.P555T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100489869; called by muse, varscan2
- COL24A1 | c.2525T>C p.V842A | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.038); catalogued as COSV100992848; called by muse, mutect2, varscan2
- COL5A2 | c.1829A>T p.Q610L | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.176); catalogued as COSV100879989; called by muse, mutect2, varscan2
- CPB1 | c.474+1G>T p.X158_splice | Splice Site (SNP) | VAF 24/146 reads (16%) | catalogued as rs756820249, COSV99294088; called by muse, mutect2, varscan2
- CPNE4 | c.541A>T p.I181F | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV101456563; called by muse, mutect2, varscan2
- CRB1 | c.1961C>T p.T654I | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.386); catalogued as rs1386890068, CM057652, COSV100957646, COSV100957758; called by muse, mutect2, varscan2
- CRB1 | c.3300A>G p.I1100M | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100957647, COSV66328610; called by muse, mutect2, varscan2
- CRYBG1 | c.4045C>G p.L1349V | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV100954370; called by muse, mutect2, varscan2
- CRYGS | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as rs764793775, COSV57192133; called by muse, mutect2, varscan2
- CSMD3 | c.5987A>G p.Y1996C (on ENST00000297405 / NM_001363185.1; = p.Y1892C on NM_052900.3) | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99823756; called by muse, mutect2, varscan2
- CUBN | c.10411G>A p.G3471R | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1453459372, COSV100912026; called by muse, mutect2, varscan2
- CUX2 | c.1390C>A p.L464M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV99918541, COSV99919296; called by muse, mutect2
- CYP27C1 | c.390C>T p.S130= | Splice Region (SNP) | VAF 23/58 reads (40%) | catalogued as rs779961606, COSV100079648; called by muse, mutect2, varscan2
- DAAM2 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.179); catalogued as COSV99224454; called by muse, mutect2, varscan2
- DAB1 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100139379, COSV59727095; called by muse, mutect2, varscan2
- DCAF8L1 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV101491377; called by muse, mutect2, varscan2
- DCC | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as COSV59119528; called by muse, mutect2, varscan2
- DGKQ | c.2632del p.R878Efs*24 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | catalogued as rs1560510031, COSV53278559; called by mutect2, pindel, varscan2
- DLG2 | c.996G>T p.K332N | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.653); catalogued as COSV99712460; called by muse, mutect2, varscan2
- DNAH7 | c.4759T>C p.F1587L | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV100413749; called by muse, mutect2, varscan2
- DNAH9 | c.831G>T p.M277I | Missense Mutation (SNP) | VAF 90/158 reads (57%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV99303889; called by muse, mutect2, varscan2
- DSP | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 88/183 reads (48%) | catalogued as COSV101131177, COSV65792926; called by muse, mutect2, varscan2
- ECHDC3 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as COSV101004520, COSV101004569; called by muse, mutect2, varscan2
- EEF2K | c.1291A>T p.N431Y | Missense Mutation (SNP) | VAF 58/268 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as COSV99532539; called by muse, mutect2, varscan2
- EFCAB13 | c.2021T>A p.L674* | Nonsense Mutation (SNP) | VAF 38/160 reads (24%) | catalogued as COSV100516329; called by muse, mutect2, varscan2
- ELAVL2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 128/453 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99805321; called by muse, mutect2, varscan2
- EPHB1 | c.1129G>C p.V377L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV101212645; called by muse, mutect2
- ERICH3 | c.2002G>T p.V668F | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV100443332, COSV58621359; called by muse, mutect2, varscan2
- EXOC4 | c.2838C>A p.N946K | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV99552206; called by muse, mutect2, varscan2
- EYS | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as COSV100675624; called by muse, mutect2, varscan2
- FAT2 | c.5479G>T p.E1827* | Nonsense Mutation (SNP) | VAF 38/106 reads (36%) | catalogued as COSV99941575; called by muse, mutect2, varscan2
- FAT2 | c.3815A>G p.D1272G | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99941578; called by muse, mutect2, varscan2
- FAT3 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99961567; called by muse, mutect2, varscan2
- FAT3 | c.1282C>A p.L428M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99961568; called by muse, mutect2, varscan2
- FAT4 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101271816; called by muse, mutect2, varscan2
- FBXL13 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs370558905, COSV50867489, COSV99978190; called by muse, mutect2, varscan2
- FDFT1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs767263162, COSV99594570; called by muse, mutect2, varscan2
- FER1L6 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV101205411; called by muse, mutect2, varscan2
- FFAR1 | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.759); catalogued as rs143187042, COSV99322802; called by muse, mutect2, varscan2
- FGF1 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as COSV100532225; called by muse, mutect2, varscan2
- FGF2 | c.526A>T p.I176F | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99144558; called by muse, mutect2, varscan2
- FIGNL2 | c.407C>G p.A136G | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.182); catalogued as COSV101626860; called by muse, mutect2
- FLT4 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs770298389, COSV99985844; called by muse, mutect2, varscan2
- FMC1 | c.333G>A p.W111* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as rs1370467561, COSV99880503; called by muse, mutect2
- FOXO4 | c.1411G>C p.D471H | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100446763; called by muse, mutect2, varscan2
- FSIP1 | c.1695A>G p.I565M | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs761249507, COSV100617944; called by muse, mutect2, varscan2
- GABRB3 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100158048; called by muse, mutect2, varscan2
- GALNTL6 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101560094; called by muse, mutect2, varscan2
- GBA3 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101545466; called by muse, mutect2
- GFRA1 | c.694G>C p.V232L | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs781774794, COSV100815417; called by muse, mutect2, varscan2
- GLI3 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs750890677, COSV67889940; called by muse, mutect2, varscan2
- GPI | c.1191A>T p.Q397H | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100731414; called by muse, mutect2, varscan2
- GPRIN3 | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV100310566; called by muse, mutect2, varscan2
- GRIA2 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99642905; called by muse, mutect2
- GRIA2 | c.2526G>T p.E842D | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV99642909; called by muse, mutect2, varscan2
- GRIN2A | c.2227G>C p.E743Q | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100408175, COSV58053099; called by muse, mutect2, varscan2
- GRIP1 | c.2108C>G p.T703S (on ENST00000359742 / NM_001379345.1; = p.T651S on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV99667875; called by muse, mutect2, varscan2
- GRM3 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862065; called by muse, mutect2, varscan2
- GRM5 | c.912T>A p.S304R | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100550057; called by muse, mutect2, varscan2
- GRXCR1 | c.430A>T p.T144S | Missense Mutation (SNP) | VAF 61/321 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV101295609, COSV67670824; called by mutect2, varscan2
- GSPT2 | c.1330A>C p.T444P | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100467893; called by muse, mutect2, varscan2
- H4C6 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as COSV66685376; called by muse, mutect2
- HAS2 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 147/458 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100391428; called by muse, mutect2, varscan2
- HBA2 | c.376C>A p.L126M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.204); catalogued as COSV99285350; called by muse, mutect2, varscan2
- HFM1 | c.2880T>A p.D960E | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV99645285; called by muse, mutect2, varscan2
- HIPK3 | c.3638C>A p.P1213Q | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100305356, COSV100306143; called by muse, mutect2, varscan2
- HIVEP1 | c.5308G>A p.G1770R | Missense Mutation (SNP) | VAF 136/274 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101044643; called by muse, mutect2, varscan2
- IFNW1 | c.557G>C p.R186T | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV101207599, COSV66522296; called by muse, mutect2, varscan2
- IKBKE | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.603); catalogued as rs202128741, COSV100898073, COSV65625613; called by muse, mutect2, varscan2
- INTS7 | c.2456T>C p.I819T | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs779809861, COSV100877372; called by muse, mutect2, varscan2
- ITGAX | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 88/360 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99191421; called by muse, varscan2
- JAK2 | c.728G>A p.C243Y | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV67584648; called by muse, mutect2, varscan2
- KDM4C | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV101184645, COSV67185189; called by muse, mutect2, varscan2
- KIF3A | c.216A>T p.K72N | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV101109212; called by muse, mutect2, varscan2
- KLHL23 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.322); catalogued as rs140221414, COSV55865633; called by muse, mutect2
- LAMA1 | c.5994A>T p.R1998S | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV101054901; called by muse, mutect2, varscan2
- LILRA4 | c.404C>G p.S135* | Nonsense Mutation (SNP) | VAF 12/124 reads (10%) | catalogued as COSV99392853; called by muse, mutect2
- LILRB3 | c.1376G>C p.G459A (on ENST00000346401; = p.G447A on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV99557019; called by muse, mutect2, varscan2
- LINGO2 | c.683A>T p.K228I | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV100430109; called by muse, mutect2, varscan2
- LRAT | c.139C>G p.R47G | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100311996; called by muse, mutect2, varscan2
- LRP1B | c.13018G>A p.D4340N | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101251919; called by muse, mutect2, varscan2
- LRP1B | c.11754A>T p.E3918D | Missense Mutation (SNP) | VAF 118/245 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.388); catalogued as COSV101251921, COSV67206541; called by muse, mutect2, varscan2
- LRP2BP | c.620T>C p.L207P | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1455084959, COSV100145862; called by muse, mutect2, varscan2
- LRP4 | c.3962C>T p.S1321F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV101066202; called by muse, mutect2, varscan2
- LRRC40 | c.1761A>T p.K587N | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100918690; called by muse, mutect2
- LRRC7 | c.4484T>C p.L1495P (on ENST00000651989 / NM_001370785.2; = p.L1415P on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99224311; called by muse, mutect2, varscan2
- LTBP3 | c.2515G>T p.G839C | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99533713; called by muse, mutect2, varscan2
- LYG1 | c.132C>A p.H44Q | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV100415802, COSV100415814; called by muse, mutect2, varscan2
- MAGEA12 | c.56A>G p.Q19R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1556833284, COSV63294455; called by muse, mutect2, varscan2
- MAGEB1 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV100974827; called by muse, mutect2, varscan2
- MAMDC4 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 29/178 reads (16%) | catalogued as rs1405228372, COSV99915377; called by muse, mutect2
- MAP2 | c.1846G>C p.G616R | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.444); catalogued as COSV99557669; called by muse, mutect2, varscan2
- MAP2K3 | c.607C>T p.H203Y (on ENST00000342679 / NM_145109.3; = p.H174Y on NM_002756.4) | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.671); catalogued as COSV100383338; called by muse, mutect2, varscan2
- MEP1A | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 149/581 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100042308; called by muse, mutect2, varscan2
- MFSD9 | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99301915; called by muse, mutect2, varscan2
- MGAM | c.3302C>A p.T1101K | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV101527365; called by muse, mutect2, varscan2
- MKRN3 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100090665; called by muse, mutect2, varscan2
- MKRN3 | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV100090667; called by muse, mutect2, varscan2
- MME | c.976T>G p.F326V | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100852221; called by muse, mutect2, varscan2
- MOG | c.710-2A>G p.X237_splice | Splice Site (SNP) | VAF 28/63 reads (44%) | catalogued as rs1242904814, COSV100971800; called by muse, mutect2, varscan2
- MON2 | c.540G>T p.M180I | Missense Mutation (SNP) | VAF 111/460 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99741512; called by muse, mutect2, varscan2
- MUC17 | c.6851T>C p.I2284T | Missense Mutation (SNP) | VAF 98/450 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs555461787; called by muse, mutect2
- MYBPC1 | c.1229C>A p.A410D (on ENST00000550270 / NM_206820.2; = p.A435D on NM_002465.4) | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV100637730; called by muse, mutect2, varscan2
- MYCBPAP | c.1635+2T>A p.X545_splice | Splice Site (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100087639; called by muse, mutect2, varscan2
- MYO18B | c.6950C>A p.A2317D | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV100122522; called by muse, mutect2, varscan2
- NAV3 | c.6625G>T p.D2209Y (on ENST00000397909 / NM_001024383.2; = p.D2187Y on NM_014903.6) | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99885995, COSV99886692; called by muse, mutect2, varscan2
- NBAS | c.2348G>T p.G783V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99866956; called by muse, mutect2, varscan2
- NEBL | c.1018A>G p.K340E | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV101009075; called by muse, mutect2
- NES | c.2207T>C p.L736P | Missense Mutation (SNP) | VAF 74/299 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV100957743; called by muse, mutect2, varscan2
- NOTCH4 | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.589); catalogued as COSV100900345; called by muse, mutect2, varscan2
- NPC1 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as rs1165354098, COSV99340761; called by muse, mutect2, varscan2
- NSD1 | c.4297A>T p.K1433* | Nonsense Mutation (SNP) | VAF 38/85 reads (45%) | catalogued as COSV61785182; called by muse, mutect2, varscan2
- NTRK3 | c.1894C>T p.H632Y | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100712228; called by muse, mutect2, varscan2
- NXF3 | c.1511G>A p.S504N | Missense Mutation (SNP) | VAF 66/102 reads (65%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV101221862; called by muse, mutect2, varscan2
- OR10K2 | c.795C>G p.N265K | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.056); catalogued as COSV100149376; called by muse, mutect2, varscan2
- OR11H12 | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 72/279 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV101612452; called by muse, mutect2, varscan2
- OR13C8 | c.634T>G p.L212V | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as COSV100622918; called by muse, mutect2, varscan2
- OR14A16 | c.911del p.G304Efs*? | Frame Shift Del (DEL) | VAF 30/139 reads (22%) | catalogued as COSV62926801, COSV62926998; called by mutect2, pindel, varscan2
- OR1D2 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.424); catalogued as COSV58921697; called by muse, mutect2, varscan2
- OR2J2 | c.578C>A p.T193N | Missense Mutation (SNP) | VAF 41/386 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV101013271; called by muse, varscan2
- OR2W1 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101013894; called by muse, mutect2, varscan2
- OR5A2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 88/293 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV100119662; called by muse, mutect2, varscan2
- OR5C1 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV101030513; called by muse, mutect2, varscan2
- OR5M3 | c.415T>C p.C139R | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392288; called by muse, mutect2, varscan2
- OR7D4 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as COSV100432576; called by muse, mutect2, varscan2
- OTULIN | c.242G>T p.S81I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99419514; called by muse, mutect2
- PAK3 | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53274468, COSV99456479; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.8T>C p.I3T (on ENST00000259318 / NM_001136562.3; = p.I234T on NM_007203.5) | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV99394667; called by muse, mutect2, varscan2
- PCDH18 | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100787009; called by muse, mutect2, varscan2
- PCDHA3 | c.1649C>T p.T550M | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); catalogued as rs782401655, COSV63538552; called by muse, mutect2, varscan2
- PCDHGA12 | c.750C>A p.S250R | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.088); catalogued as COSV52749810, COSV99337806; called by muse, mutect2, varscan2
- PCDHGA2 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as COSV53964169; called by muse, mutect2
- PCLO | c.13402G>T p.V4468F | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as COSV100427126, COSV61665116; called by muse, mutect2, varscan2
- PCSK1 | c.269T>C p.L90S | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100226788; called by muse, mutect2, varscan2
- PDE8B | c.399+2T>A p.X133_splice | Splice Site (SNP) | VAF 33/242 reads (14%) | catalogued as COSV99366064; called by muse, mutect2, varscan2
- PEX5L | c.605G>C p.R202T | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as COSV55849678; called by muse, mutect2, varscan2
- PITPNM1 | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs1272992370, COSV99653498; called by muse, mutect2, varscan2
- PLEC | c.1391T>A p.M464K (on ENST00000322810 / NM_201380.4; = p.M354K on NM_000445.5) | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100510355; called by muse, mutect2, varscan2
- PLOD2 | c.405A>C p.K135N | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.889); catalogued as COSV99282313; called by muse, mutect2, varscan2
- PPP1R3B | c.651T>A p.N217K | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.023); catalogued as COSV100133884; called by muse, mutect2, varscan2
- PRDM12 | c.335C>A p.T112N | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99446027; called by muse, mutect2, varscan2
- PRL | c.615G>T p.R205S | Missense Mutation (SNP) | VAF 171/329 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV100122927; called by muse, mutect2, varscan2
- PRXL2A | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 24/197 reads (12%) | catalogued as rs776396632, COSV64690876; called by muse, mutect2, varscan2
- PTPRM | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV100154654, COSV59848075; called by muse, mutect2, varscan2
- PURG | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 44/164 reads (27%) | catalogued as COSV99988220; called by muse, mutect2, varscan2
- PXMP2 | c.123-1G>A p.X41_splice | Splice Site (SNP) | VAF 41/174 reads (24%) | catalogued as COSV100265269; called by muse, mutect2, varscan2
- QSOX1 | c.1758G>T p.M586I | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100852802; called by muse, varscan2
- R3HDM1 | c.284A>C p.E95A | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV99925640; called by muse, mutect2, varscan2
- RAI14 | c.1813C>A p.Q605K | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV54293990, COSV99461781; called by muse, mutect2, varscan2
- RAPGEF6 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 20/135 reads (15%) | catalogued as COSV99725093; called by muse, mutect2, varscan2
- RASGRF2 | c.543G>A p.E181= | Splice Region (SNP) | VAF 12/132 reads (9%) | catalogued as COSV99428470; called by muse, mutect2
- RELN | c.6818G>A p.G2273D | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as COSV100632301; called by muse, mutect2, varscan2
- RNF175 | c.364A>G p.R122G | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV99923875; called by muse, mutect2, varscan2
- ROBO2 | c.60T>A p.D20E | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100164035; called by muse, mutect2, varscan2
- ROR2 | c.1740C>A p.D580E | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as COSV100995450; called by muse, mutect2, varscan2
- RSRC1 | c.550A>C p.K184Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99905332; called by muse, mutect2, varscan2
- RUNDC1 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV100865777; called by muse, mutect2, varscan2
- RUNX1T1 | c.548C>T p.P183L (on ENST00000265814 / NM_001198628.1; = p.P156L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56137178, COSV56139942, COSV56141276; called by muse, mutect2, varscan2
- RXRG | c.849G>T p.W283C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63233373; called by muse, mutect2, varscan2
- RXRG | c.848G>A p.W283* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100717725, COSV63232009; called by muse, mutect2, varscan2
- RYR2 | c.2456A>G p.Y819C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100767620; called by muse, mutect2
- SACS | c.8723A>T p.D2908V | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV66540724; called by muse, mutect2, varscan2
- SCG2 | c.1223G>C p.R408T | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100544587; called by muse, mutect2, varscan2
- SEC24B | c.2525G>A p.G842D | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV99492825; called by muse, mutect2, varscan2
- SEMA3A | c.1562G>C p.G521A | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99545159; called by muse, mutect2, varscan2
- SEPTIN9 | c.1475G>C p.R492P (on ENST00000427177 / NM_001113491.2; = p.R474P on NM_006640.4) | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100217443, COSV61203615; called by muse, mutect2
- SERPINA4 | c.776G>A p.R259K | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as rs868521108, COSV100096927, COSV54071429; called by muse, mutect2, varscan2
- SHISA3 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 94/359 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100069772, COSV59980402; called by muse, mutect2, varscan2
- SLC17A6 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV54137291, COSV99580657; called by muse, mutect2, varscan2
- SLC44A3 | c.1181T>A p.I394N (on ENST00000271227 / NM_001114106.3; = p.I346N on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99597762; called by muse, mutect2, varscan2
- SLC44A3 | c.1482G>C p.Q494H (on ENST00000271227 / NM_001114106.3; = p.Q446H on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as rs1182215290, COSV99597766; called by muse, mutect2, varscan2
- SLC4A8 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as COSV100176416; called by muse, mutect2, varscan2
- SLC6A9 | c.1181G>A p.R394Q (on ENST00000360584 / NM_201649.4; = p.R340Q on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201870833, COSV62210080; called by muse, mutect2, varscan2
- SLCO6A1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs773104457, COSV65805365; called by muse, mutect2, varscan2
- SLIT2 | c.2416T>A p.L806I | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99880612, COSV99887336; called by muse, mutect2, varscan2
- SLITRK4 | c.1118T>C p.I373T | Missense Mutation (SNP) | VAF 107/191 reads (56%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1556427262, COSV100567126; called by muse, mutect2, varscan2
- SMARCA4 | c.3659A>G p.Y1220C | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100758116; called by muse, mutect2, varscan2
- SORCS3 | c.3602T>C p.I1201T | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV100864453; called by muse, mutect2, varscan2
- ST14 | c.682T>A p.F228I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as COSV99598461; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.757T>C p.Y253H | Missense Mutation (SNP) | VAF 20/100 reads (20%) | PolyPhen probably damaging (1); catalogued as rs1214951998, COSV100081479; called by muse, mutect2, varscan2
- SUN1 | c.1328G>T p.G443V (on ENST00000405266 / NM_001367651.1; = p.G323V on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.516); catalogued as COSV100568520; called by muse, mutect2, varscan2
- SUPT3H | c.676G>A p.V226I (on ENST00000371460 / NM_181356.3; = p.V215I on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/345 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100176080; called by muse, mutect2
- SYNE2 | c.16300G>C p.E5434Q | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV59951608; called by muse, mutect2, varscan2
- TAFA1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.155); catalogued as rs780034173, COSV101524350; called by muse, mutect2, varscan2
- TANC1 | c.4001T>A p.L1334* | Nonsense Mutation (SNP) | VAF 75/143 reads (52%) | catalogued as COSV99713022; called by muse, mutect2, varscan2
- TAS2R39 | c.407T>A p.F136Y | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.962); catalogued as COSV101489390; called by muse, mutect2, varscan2
- TBX22 | c.670G>T p.V224L | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.182); catalogued as COSV100960594, COSV64786372; called by muse, mutect2, varscan2
- TFAP4 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); catalogued as rs762237536, COSV99200025; called by muse, mutect2, varscan2
- TH | c.605C>A p.S202* (on ENST00000381178 / NM_199292.3; = p.S171* on NM_000360.4) | Nonsense Mutation (SNP) | VAF 27/88 reads (31%) | catalogued as COSV100147040; called by muse, mutect2, varscan2
- THNSL2 | c.872T>A p.I291N | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100147302; called by muse, mutect2, varscan2
- TIGD2 | c.841A>C p.K281Q | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as COSV100392266; called by muse, mutect2, varscan2
- TMEM132D | c.465C>A p.D155E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs372489586; called by muse, mutect2, varscan2
- TMEM144 | c.122A>G p.Q41R | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99646610; called by muse, varscan2
- TMTC3 | c.2414A>G p.E805G | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV99898008; called by muse, mutect2, varscan2
- TNC | c.1038C>A p.C346* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | catalogued as COSV100404906, COSV60785372; called by muse, mutect2, varscan2
- TTN | c.24224C>A p.S8075Y (on ENST00000591111; = p.S7148Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | PolyPhen probably damaging (0.945); catalogued as COSV100593157; called by muse, mutect2, varscan2
- TUBGCP6 | c.4918G>A p.A1640T | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99954790; called by muse, mutect2, varscan2
- VGF | c.1751G>C p.R584P | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.307); catalogued as rs771527523, COSV99972816; called by muse, mutect2, varscan2
- WDR17 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 84/331 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54570726, COSV99706693; called by muse, mutect2, varscan2
- WDR17 | c.3680C>A p.S1227Y | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99706694; called by muse, mutect2, varscan2
- WDR73 | c.23T>A p.L8Q | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100850524; called by muse, mutect2, varscan2
- WNT7A | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs751362548, COSV53199436; called by muse, mutect2, varscan2
- XRN1 | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99377164; called by muse, mutect2, varscan2
- YTHDF3 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV101572353; called by muse, mutect2, varscan2
- ZEB1 | c.2271G>C p.Q757H | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1035424862, COSV100313587; called by muse, mutect2, varscan2
- ZIC2 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100891756, COSV66255130; called by muse, mutect2, varscan2
- ZNF330 | c.906G>T p.L302F | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV99522418; called by muse, mutect2, varscan2
- ZNF334 | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs765835222, COSV100748973; called by muse, mutect2, varscan2
- ZNF429 | c.2020G>T p.G674C | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.669); catalogued as COSV100641760; called by muse, mutect2
- ZNF43 | c.515A>C p.K172T | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100731668, COSV61684341; called by muse, mutect2
- ZNF521 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs751210489, COSV100831384; called by muse, mutect2, varscan2
- ZNF536 | c.3203T>C p.M1068T | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1568542427, COSV100834606; called by muse, mutect2, varscan2
- ZNF696 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747408998, COSV100350372; called by muse, varscan2
- ZNF85 | c.489A>T p.R163S | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs756180221, COSV100059447; called by muse, mutect2
- ZRANB2 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV99638894; called by muse, mutect2
- ATP13A5 | c.2915dup p.L973Ffs*31 | Frame Shift Ins (INS) | VAF 24/147 reads (16%) | called by mutect2, pindel, varscan2
- CFAP92 | c.211dup p.H71Pfs*28 | Frame Shift Ins (INS) | VAF 104/436 reads (24%) | called by mutect2, pindel, varscan2
- EPHA4 | c.2021dup p.M674Ifs*5 | Frame Shift Ins (INS) | VAF 23/200 reads (12%) | called by mutect2, pindel, varscan2
- FAT1 | c.3672dup p.K1225Qfs*13 | Frame Shift Ins (INS) | VAF 98/581 reads (17%) | called by mutect2, pindel, varscan2
- HOXD9 | c.200G>T p.S67I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- HTR7 | c.254del p.G85Afs*4 | Frame Shift Del (DEL) | VAF 26/99 reads (26%) | called by mutect2, pindel, varscan2
- IGHG1 | c.742del p.L248* | Frame Shift Del (DEL) | VAF 87/286 reads (30%) | called by mutect2, pindel, varscan2
- IGHV1-58 | c.124A>T p.K42* | Nonsense Mutation (SNP) | VAF 34/120 reads (28%) | called by muse, mutect2, varscan2
- ITIH5 | c.74del p.G25Afs*21 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | called by mutect2, pindel, varscan2
- KMT2D | c.3103dup p.Q1035Pfs*33 | Frame Shift Ins (INS) | VAF 28/90 reads (31%) | called by mutect2, pindel, varscan2
- OR4C6 | c.458dup p.H153Qfs*18 | Frame Shift Ins (INS) | VAF 21/187 reads (11%) | called by mutect2, pindel, varscan2
- OR52D1 | c.610A>G p.T204A | Missense Mutation (SNP) | VAF 116/356 reads (33%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PCDH7 | c.2645G>T p.R882L | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRAG1 | c.4165dup p.A1389Gfs*59 | Frame Shift Ins (INS) | VAF 27/105 reads (26%) | called by mutect2, pindel, varscan2
- SELE | c.1036del p.Q346Rfs*33 | Frame Shift Del (DEL) | VAF 27/165 reads (16%) | called by mutect2, pindel, varscan2
- SLCO2B1 | c.125del p.P42Qfs*23 | Frame Shift Del (DEL) | VAF 51/217 reads (24%) | called by mutect2, pindel, varscan2
- SVEP1 | c.9397del p.A3133Qfs*12 | Frame Shift Del (DEL) | VAF 48/188 reads (26%) | called by mutect2, pindel, varscan2
- TPTE | c.906C>G p.I302M (on ENST00000618007 / NM_199261.4; = p.I284M on NM_199259.4) | Missense Mutation (SNP) | VAF 46/364 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- TRBV30 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNRF3 | c.2381dup p.S795Qfs*6 (on ENST00000544604 / NM_001206998.2; = p.S695Qfs*6 on NM_032173.3) | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | called by mutect2, varscan2
- AL021546.1 | c.69G>T p.A23= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as COSV99984797; called by muse, mutect2, varscan2
- ALX4 | c.604T>C p.L202= | Silent (SNP) | VAF 104/299 reads (35%) | catalogued as rs1240869732, COSV100240872; called by muse, mutect2, varscan2
- AMY2B | c.453T>C p.F151= | Silent (SNP) | VAF 84/1098 reads (8%) | catalogued as rs770833106, COSV63715189; called by muse, mutect2
- ANK2 | c.8313C>T p.I2771= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV52159304, COSV52168180; called by muse, mutect2, varscan2
- ANKS1B | c.3129C>A p.T1043= (on ENST00000547776 / NM_152788.4; = p.T209= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100227121; called by muse, mutect2, varscan2
- APOBEC3D | c.468T>C p.R156= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as rs371920813; called by muse, mutect2, varscan2
- ARFGEF1 | c.4716T>C p.I1572= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as COSV51611212, COSV99141071; called by muse, mutect2, varscan2
- ATP2A3 | c.1935G>A p.T645= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as rs139395876; called by muse, mutect2, varscan2
- BPI | c.1059C>A p.T353= (on ENST00000262865; = p.T349= on NM_001725.3) | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99480381; called by muse, mutect2, varscan2
- CATSPER2 | c.1095C>T p.D365= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs144799666; called by muse, mutect2, varscan2
- CCNB1 | c.1296G>A p.K432= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as COSV99841196; called by muse, mutect2
- CDH2 | c.741G>A p.V247= | Silent (SNP) | VAF 65/202 reads (32%) | catalogued as COSV99295567; called by muse, mutect2, varscan2
- CDK11B | c.1752G>A p.A584= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs368832250; called by muse, mutect2, varscan2
- CEP57 | c.1386G>A p.K462= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV100334562; called by muse, mutect2, varscan2
- CNTN4 | c.168A>T p.P56= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as COSV101281143; called by muse, mutect2, varscan2
- CYTH4 | c.1044C>A p.G348= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV99957740; called by muse, mutect2, varscan2
- DAAM2 | c.1968C>T p.S656= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV99224461, COSV99227082; called by muse, varscan2
- DHX36 | c.1581G>A p.L527= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100273288; called by muse, mutect2, varscan2
- DMTF1 | c.1356C>T p.A452= | Silent (SNP) | VAF 97/431 reads (23%) | catalogued as COSV100487234; called by muse, mutect2, varscan2
- DOCK10 | c.5586A>G p.K1862= | Silent (SNP) | VAF 102/204 reads (50%) | catalogued as COSV99287482; called by muse, mutect2, varscan2
- DOT1L | c.4002T>C p.G1334= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV67110939; called by mutect2, varscan2
- ELF2 | c.930T>C p.D310= (on ENST00000379550 / NM_001331036.2; = p.D250= on NM_006874.4) | Silent (SNP) | VAF 49/264 reads (19%) | catalogued as COSV99642501; called by muse, mutect2, varscan2
- ERBB2 | c.2004G>T p.G668= | Silent (SNP) | VAF 53/215 reads (25%) | catalogued as COSV99506562; called by muse, mutect2, varscan2
- FAM222B | c.1503C>A p.G501= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV100368174, COSV57928269; called by muse, mutect2, varscan2
- GLRB | c.897G>T p.V299= | Silent (SNP) | VAF 21/181 reads (12%) | catalogued as COSV100029444; called by muse, mutect2, varscan2
- GPR149 | c.1956A>T p.L652= | Silent (SNP) | VAF 82/339 reads (24%) | catalogued as rs773128964, COSV101078092; called by muse, mutect2, varscan2
- GPR179 | c.5820A>T p.T1940= (on ENST00000621958; = p.T1939= on NM_001004334.4) | Silent (SNP) | VAF 33/144 reads (23%) | called by muse, mutect2, varscan2
- GRM6 | c.2232C>T p.C744= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs754013842, COSV99179439; called by muse, mutect2
- H4C2 | c.144C>T p.S48= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as rs141516292, COSV55140148; called by muse, mutect2, varscan2
- IGSF9 | c.3295C>T p.L1099= (on ENST00000368094 / NM_001135050.2; = p.L1083= on NM_020789.4) | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV100230947; called by muse, mutect2, varscan2
- IL21 | c.156T>C p.Y52= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as rs1429187449, COSV52646934, COSV99144476; called by muse, mutect2, varscan2
- IPO9 | c.2403C>T p.V801= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV100843323; called by muse, mutect2, varscan2
- KRT33A | c.1104C>T p.P368= | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as COSV99144771; called by muse, mutect2
- LAMC1 | c.4245T>G p.A1415= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99278906; called by muse, mutect2
- LHX2 | c.204G>T p.A68= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV65318493; called by muse, mutect2, varscan2
- LRRC6 | c.1092T>C p.S364= | Silent (SNP) | VAF 48/256 reads (19%) | catalogued as COSV99137715; called by muse, mutect2, varscan2
- LRRC74A | c.1116G>T p.V372= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV99372162; called by muse, mutect2, varscan2
- MAGEB4 | c.204C>G p.T68= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV100854600; called by muse, mutect2, varscan2
- MAGEC1 | c.1317C>T p.P439= | Silent (SNP) | VAF 109/221 reads (49%) | catalogued as COSV99594791, COSV99596482; called by muse, varscan2
- MGAT3 | c.615G>A p.P205= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1446059301, COSV100361704; called by muse, mutect2, varscan2
- MIPOL1 | c.756G>A p.K252= | Silent (SNP) | VAF 50/196 reads (26%) | catalogued as COSV100538065; called by muse, mutect2, varscan2
- MMD | c.582C>T p.F194= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs896408828, COSV100017768; called by muse, mutect2, varscan2
- MMP1 | c.1020C>T p.V340= | Silent (SNP) | VAF 33/216 reads (15%) | catalogued as COSV100187771; called by muse, mutect2, varscan2
- MUC17 | c.6849T>C p.S2283= | Silent (SNP) | VAF 98/460 reads (21%) | catalogued as rs540344431; called by muse, mutect2
- MYRIP | c.1947C>A p.V649= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV100218282; called by muse, mutect2, varscan2
- NARS2 | c.324G>T p.V108= | Silent (SNP) | VAF 56/182 reads (31%) | catalogued as COSV104384416, COSV99806911; called by muse, mutect2, varscan2
- NECAB1 | c.555C>T p.R185= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs766524205, COSV101341001; called by muse, mutect2, varscan2
- NEFM | c.243G>T p.S81= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV55332744, COSV99646925; called by muse, mutect2, varscan2
- NELL1 | c.669A>G p.L223= | Silent (SNP) | VAF 71/176 reads (40%) | catalogued as COSV100118724; called by muse, mutect2, varscan2
- NELL1 | c.1818C>T p.T606= | Silent (SNP) | VAF 74/221 reads (33%) | catalogued as COSV100118727; called by muse, mutect2, varscan2
- NEUROD6 | c.456C>T p.I152= | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as rs533417088, COSV51771941; called by muse, mutect2, varscan2
- NLGN4Y | c.2415A>T p.T805= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV100196335; called by muse, mutect2, varscan2
- NOBOX | c.1066C>A p.R356= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV56193667, COSV56194207; called by muse, mutect2, varscan2
- NR3C2 | c.303A>G p.V101= | Silent (SNP) | VAF 44/217 reads (20%) | catalogued as rs754862955, COSV100678634; called by muse, mutect2, varscan2
- OR4L1 | c.669C>A p.V223= | Silent (SNP) | VAF 60/247 reads (24%) | catalogued as COSV59850292, COSV59850994; called by muse, mutect2, varscan2
- OR5K2 | c.582C>T p.I194= | Silent (SNP) | VAF 213/591 reads (36%) | catalogued as COSV101415947; called by muse, mutect2, varscan2
- OR6K2 | c.606C>G p.V202= | Silent (SNP) | VAF 37/167 reads (22%) | catalogued as COSV100656681, COSV62744216; called by muse, mutect2, varscan2
- PCDH15 | c.480T>A p.T160= | Silent (SNP) | VAF 36/248 reads (15%) | catalogued as COSV100214738; called by muse, mutect2, varscan2
- PCDHA11 | c.1812G>T p.A604= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV56532473, COSV56548371; called by muse, mutect2, varscan2
- PCDHB5 | c.1449C>T p.A483= | Silent (SNP) | VAF 65/218 reads (30%) | catalogued as rs782338686, COSV50676647; called by muse, mutect2, varscan2
- PDZRN3 | c.1929C>T p.C643= | Silent (SNP) | VAF 42/166 reads (25%) | catalogued as rs368693865, COSV55205808; called by muse, mutect2, varscan2
- PLIN4 | c.3876G>A p.R1292= (on ENST00000301286; = p.R1307= on NM_001367868.2) | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1309102904, COSV100012087; called by muse, varscan2
- PRAG1 | c.354C>G p.G118= | Silent (SNP) | VAF 43/200 reads (22%) | catalogued as COSV100421815; called by muse, mutect2, varscan2
- PRDM9 | c.2622C>T p.S874= | Silent (SNP) | VAF 35/165 reads (21%) | catalogued as rs376505927, COSV99689728; called by muse, mutect2, varscan2
- RAPGEF3 | c.1422C>A p.A474= (on ENST00000389212; = p.A432= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV99405785; called by muse, mutect2, varscan2
- RELN | c.9855C>A p.T3285= | Silent (SNP) | VAF 48/206 reads (23%) | catalogued as COSV100632299; called by muse, varscan2
- RIC1 | c.2559A>G p.T853= | Silent (SNP) | VAF 34/165 reads (21%) | catalogued as rs147383296; called by muse, mutect2, varscan2
- ROBO4 | c.1740T>C p.T580= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV100127272; called by muse, mutect2, varscan2
- RPL10A | c.648A>G p.L216= | Silent (SNP) | VAF 71/148 reads (48%) | catalogued as rs1341343922, COSV100003160; called by muse, mutect2, varscan2
- RUNDC1 | c.810G>C p.L270= | Silent (SNP) | VAF 37/128 reads (29%) | catalogued as rs765079678, COSV100865778, COSV100865911; called by muse, varscan2
- RYR2 | c.11565G>A p.Q3855= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs763196179, COSV100767621; called by muse, varscan2
- SOX11 | c.78C>T p.F26= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100430734; called by muse, mutect2, varscan2
- SPG11 | c.1599A>T p.L533= | Silent (SNP) | VAF 51/175 reads (29%) | catalogued as COSV99968000; called by muse, varscan2
- SPTA1 | c.6624G>A p.A2208= | Silent (SNP) | VAF 101/316 reads (32%) | catalogued as rs763473161, COSV63749224; called by muse, mutect2, varscan2
- STAB1 | c.7554T>C p.D2518= | Silent (SNP) | VAF 40/301 reads (13%) | catalogued as rs772290528, COSV100194499; called by muse, mutect2
- SYNE1 | c.8745G>C p.G2915= (on ENST00000367255 / NM_182961.4; = p.G2922= on NM_033071.3) | Silent (SNP) | VAF 111/271 reads (41%) | catalogued as COSV99552300; called by muse, mutect2, varscan2
- TCAF1 | c.405A>G p.T135= | Silent (SNP) | VAF 67/205 reads (33%) | catalogued as COSV100584546; called by muse, mutect2, varscan2
- TEKT2 | c.807G>T p.L269= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV99255375; called by muse, mutect2, varscan2
- TPCN1 | c.2220G>T p.L740= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100136384, COSV59234035; called by muse, mutect2, varscan2
- TRBV4-1 | c.66A>G p.E22= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as rs1186356992; called by muse, mutect2
- TRIM26 | c.531G>A p.A177= | Silent (SNP) | VAF 18/254 reads (7%) | catalogued as rs759675894, COSV101359414; called by muse, mutect2
- UBE2I | c.468G>T p.A156= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV100330389, COSV100330479; called by muse, mutect2, varscan2
- UNC80 | c.156G>A p.V52= | Silent (SNP) | VAF 98/211 reads (46%) | catalogued as rs371036835; called by muse, mutect2, varscan2
- USH2A | c.7338C>T p.A2446= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as rs1438605138, COSV100228553; called by muse, mutect2, varscan2
- ZBTB41 | c.2448G>A p.Q816= | Silent (SNP) | VAF 52/177 reads (29%) | catalogued as COSV100962800; called by muse, mutect2, varscan2
- ZNF597 | c.666C>T p.R222= | Silent (SNP) | VAF 81/280 reads (29%) | catalogued as rs753460930, COSV100071877; called by muse, mutect2, varscan2
- ZSCAN1 | c.1056C>A p.P352= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs374905480; called by muse, mutect2, varscan2
- AGAP7P | n.1760C>T | RNA (SNP) | VAF 15/180 reads (8%) | catalogued as rs781838755; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700647 G>A | 3'Flank (SNP) | VAF 12/48 reads (25%) | catalogued as rs1436618796; called by muse, mutect2, varscan2
- CSH1 | c.456+12G>T | Intron (SNP) | VAF 59/215 reads (27%) | catalogued as rs750903185, COSV100298177, COSV100298201, COSV60242731; called by muse, mutect2, varscan2
- DCHS2 | n.7900C>G | RNA (SNP) | VAF 53/160 reads (33%) | catalogued as COSV100601023; called by muse, mutect2, varscan2
- DCHS2 | n.7492C>T | RNA (SNP) | VAF 44/209 reads (21%) | catalogued as COSV100601024; called by muse, mutect2, varscan2
- GRM8 | c.727+48364C>T | Intron (SNP) | VAF 11/56 reads (20%) | catalogued as rs770921421, COSV100280517; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85964C>A | Intron (SNP) | VAF 72/411 reads (18%) | catalogued as COSV72277990; called by muse, mutect2, varscan2
- MFSD4B | c.*1040C>G | 3'UTR (SNP) | VAF 29/115 reads (25%) | catalogued as COSV100920540; called by muse, mutect2, varscan2
- MIR527 | n.9T>C | RNA (SNP) | VAF 68/267 reads (25%) | called by muse, mutect2, varscan2
- SH3TC1 | c.3131+321A>G | Intron (SNP) | VAF 18/75 reads (24%) | catalogued as rs561427785, COSV55288113; called by muse, mutect2, varscan2
- SNORD115-1 | n.82C>A | RNA (SNP) | VAF 106/437 reads (24%) | called by muse, mutect2, varscan2
- TCP10L3 | n.625C>T | RNA (SNP) | VAF 49/334 reads (15%) | catalogued as COSV100832931; called by muse, mutect2, varscan2
- ZNF99 | c.*251A>G | 3'UTR (SNP) | VAF 29/182 reads (16%) | catalogued as rs779213588, COSV101233686; called by muse, mutect2, varscan2
